Somatic mutation profile of tumor specimen TCGA-EE-A29E-06A (aliquot TCGA-EE-A29E-06A-11D-A197-08) from TCGA case TCGA-EE-A29E, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 54.7 years (19,991 days).
Specimen TCGA-EE-A29E-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dcc85343-5c10-4670-92c3-e3a5c6d7ee1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A29E-10A (Blood Derived Normal), aliquot TCGA-EE-A29E-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d57fd212-4d04-4293-8cbc-3fdc10da5279

The open-access MAF lists 4,179 somatic variants for this specimen: 2,669 protein-altering or splice-affecting, 1,420 silent, 90 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,448, Silent 1,420, Nonsense Mutation 149, RNA 34, Splice Region 31, Intron 31, Splice Site 31, 5'UTR 8, 3'UTR 6, 3'Flank 6, 5'Flank 5, Frame Shift Del 4.

Variants (750 of 4,179; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/86 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/85 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CASK | c.1480C>T p.Q494* | Nonsense Mutation (SNP) | VAF 20/22 reads (91%) | catalogued as rs1064796879, COSV59373120; ClinVar: pathogenic / not provided; called by mutect2, varscan2
- CDKN2A | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 94/158 reads (59%) | hotspot (GDC flag); catalogued as rs864622636, CM023895, COSV58683786; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 98/126 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs281874722, CS109095, COSV60368432; ClinVar: pathogenic; called by muse, varscan2
- KIF11 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 155/415 reads (37%) | catalogued as rs1554859966, COSV53272962; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NEXMIF | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 44/54 reads (81%) | catalogued as rs878854425, COSV50022161; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PASD1 | c.1014G>A p.M338I | Missense Mutation (SNP) | VAF 19/24 reads (79%) | hotspot (GDC flag); SIFT tolerated (0.63); PolyPhen benign (0.033); catalogued as COSV64856284; called by muse, mutect2, varscan2
- RAG1 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as rs878853004, CM1514428, COSV55027461; ClinVar: likely pathogenic; called by mutect2, varscan2
- TUBB8 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs869025272, CM160731, COSV100226026; ClinVar: pathogenic; called by mutect2, varscan2
- AADAC | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51760867; called by muse, mutect2, varscan2
- AADACL2 | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62930201; called by mutect2, varscan2
- AAR2 | c.970C>T p.L324F | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57924690; called by muse, varscan2
- AASDH | c.1957C>T p.Q653* | Nonsense Mutation (SNP) | VAF 75/190 reads (39%) | catalogued as COSV52709284; called by mutect2, varscan2
- AASDHPPT | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.608); catalogued as COSV53788298; called by muse, mutect2, varscan2
- ABCA10 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 99/120 reads (83%) | SIFT tolerated (0.48); PolyPhen benign (0.145); catalogued as COSV52227814; called by muse, mutect2, varscan2
- ABCA12 | c.7240G>A p.D2414N (on ENST00000272895 / NM_173076.3; = p.D2096N on NM_015657.3) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55970811; called by muse, mutect2
- ABCA12 | c.6248C>T p.S2083F (on ENST00000272895 / NM_173076.3; = p.S1765F on NM_015657.3) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV55955359; called by muse, mutect2, varscan2
- ABCA12 | c.5494G>A p.E1832K (on ENST00000272895 / NM_173076.3; = p.E1514K on NM_015657.3) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV55970836; called by muse, mutect2, varscan2
- ABCA4 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as CM132927, COSV64676550; called by muse, varscan2
- ABCA6 | c.759G>A p.M253I | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52643109; called by mutect2, varscan2
- ABCA6 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV52643119; called by muse, mutect2, varscan2
- ABCA8 | c.3665G>A p.R1222K | Missense Mutation (SNP) | VAF 62/70 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as rs773428007, COSV52209111; called by muse, mutect2, varscan2
- ABCA9 | c.2401G>A p.D801N | Missense Mutation (SNP) | VAF 66/78 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV60625299, COSV60629114; called by muse, mutect2, varscan2
- ABCB1 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55959962; called by muse, mutect2, varscan2
- ABCB5 | c.1870-1G>A p.X624_splice (on ENST00000404938 / NM_001163941.2; = p.X179_splice on NM_178559.6) | Splice Site (SNP) | VAF 13/35 reads (37%) | catalogued as COSV99328179; called by muse, varscan2
- ABCB5 | c.1870G>A p.D624N (on ENST00000404938 / NM_001163941.2; = p.D179N on NM_178559.6) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.139); catalogued as rs534768118, COSV51710085; called by muse, varscan2
- ABCC1 | c.49-1G>A p.X17_splice | Splice Site (SNP) | VAF 12/40 reads (30%) | catalogued as COSV60691679; called by muse, mutect2
- ABCC1 | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs761719926, COSV100579332; called by muse, mutect2, varscan2
- ABCC12 | c.3781G>A p.E1261K | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1326023106, COSV60917040; called by muse, varscan2
- ABCC8 | c.2374C>T p.P792S | Missense Mutation (SNP) | VAF 145/354 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.084); catalogued as COSV56855627; called by muse, mutect2, varscan2
- ABCC9 | c.2557G>A p.E853K | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as rs1207537871, COSV53981828, COSV53981949; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABHD16A | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 93/235 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65452339; called by muse, mutect2, varscan2
- AC004593.2 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as COSV56099052, COSV99765643; called by mutect2, varscan2
- AC007040.2 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV99730372; called by muse, mutect2, varscan2
- AC100868.1 | c.2008G>A p.A670T | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.015); catalogued as COSV51840697; called by muse, varscan2
- ACAD10 | c.2707C>T p.P903S | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as COSV58161341; called by muse, mutect2, varscan2
- ACAN | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV61366960; called by muse, mutect2, varscan2
- ACAT2 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65454690; called by muse, mutect2, varscan2
- ACOT12 | c.571C>G p.P191A | Missense Mutation (SNP) | VAF 90/136 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100296878, COSV100297170; called by muse, mutect2, varscan2
- ACP1 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV55242786, COSV55244959; called by muse, mutect2, varscan2
- ACSBG2 | c.1049G>A p.R350K | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53127009; called by muse, mutect2, varscan2
- ACSM2B | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 74/322 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61657166; called by mutect2, varscan2
- ACSM2B | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV61659390; called by muse, mutect2, varscan2
- ACSM4 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV101257490, COSV68068944; called by muse, mutect2, varscan2
- ACSM6 | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 24/55 reads (44%) | catalogued as COSV58979870; called by muse, mutect2, varscan2
- ACSS3 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54098600; called by muse, mutect2, varscan2
- ACSS3 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs185881304, COSV99699223; called by muse, mutect2, varscan2
- ACSS3 | c.1726C>T p.L576F | Missense Mutation (SNP) | VAF 104/250 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1346007038, COSV54098616; called by muse, mutect2, varscan2
- ACSS3 | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs747840747, COSV54089221; called by muse, mutect2, varscan2
- ACTN2 | c.738G>A p.M246I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.764); catalogued as COSV63977371, COSV63977464; called by mutect2, varscan2
- ACTRT1 | c.916C>T p.L306F | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV64419240; called by muse, mutect2, varscan2
- ADA2 | c.553A>C p.N185H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.233); catalogued as COSV99375964; called by muse, mutect2, varscan2
- ADAD1 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.506); catalogued as COSV56646364; called by muse, mutect2, varscan2
- ADAM18 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749421107, COSV55847880; called by muse, mutect2, varscan2
- ADAM18 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 76/94 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV55845094; called by muse, mutect2, varscan2
- ADAM21 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 60/87 reads (69%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV50789964; called by muse, mutect2, varscan2
- ADAM28 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 58/71 reads (82%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV56103991; called by muse, mutect2, varscan2
- ADAM28 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 58/73 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303422157, COSV56099428, COSV56099824; called by muse, mutect2, varscan2
- ADAM30 | c.1415G>A p.G472E | Missense Mutation (SNP) | VAF 188/438 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867694217, COSV65561809; called by muse, mutect2, varscan2
- ADAM33 | c.2332+1G>A p.X778_splice | Splice Site (SNP) | VAF 8/15 reads (53%) | catalogued as rs1183697336, COSV62936341; called by muse, mutect2, varscan2
- ADAMTS10 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.013); catalogued as COSV54357980; called by mutect2, varscan2
- ADAMTS13 | c.1540C>T p.R514W | Missense Mutation (SNP) | VAF 65/84 reads (77%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.637); catalogued as rs370215524, COSV63022783; called by mutect2, varscan2
- ADAMTS20 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV67132452, COSV67137047; called by muse, varscan2
- ADAMTS6 | c.1633G>A p.G545R | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.81); PolyPhen benign (0.047); catalogued as COSV66863413; called by muse, mutect2, varscan2
- ADAMTS7 | c.3872C>T p.S1291F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.191); catalogued as COSV66308923; called by muse, mutect2, varscan2
- ADAMTS8 | c.1918G>A p.A640T | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99960805; called by muse, mutect2, varscan2
- ADAMTS9 | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 180/466 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); catalogued as COSV55787712; called by muse, mutect2, varscan2
- ADAMTSL3 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 108/226 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54458911; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4444G>A p.D1482N | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.825); catalogued as COSV54442342, COSV54462512; called by muse, mutect2, varscan2
- ADAP2 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1292639951, COSV58296004; called by muse, mutect2, varscan2
- ADARB2 | c.1661C>T p.S554F | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67232977; called by mutect2, varscan2
- ADCY1 | c.1394T>A p.F465Y | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.84); PolyPhen benign (0.07); catalogued as COSV52040179; called by mutect2, varscan2
- ADCY1 | c.2716G>A p.E906K | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs762539339, COSV52040192; called by mutect2, varscan2
- ADCY1 | c.3190C>T p.Q1064* | Nonsense Mutation (SNP) | VAF 40/102 reads (39%) | catalogued as COSV52040214; called by muse, varscan2
- ADCY1 | c.3257G>A p.R1086H | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.123); catalogued as rs1162359516, COSV52040225; called by muse, varscan2
- ADCY2 | c.2945G>A p.G982E | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.287); catalogued as COSV100602604; called by muse, mutect2, varscan2
- ADCY4 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53476819; called by muse, mutect2, varscan2
- ADCY7 | c.2375G>A p.W792* | Nonsense Mutation (SNP) | VAF 46/144 reads (32%) | catalogued as COSV54269712; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.025); catalogued as rs1307857192, COSV100416360, COSV58441241; called by mutect2, varscan2
- ADGRA1 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV74142926; called by muse, mutect2, varscan2
- ADGRB2 | c.4661C>T p.S1554L (on ENST00000373658 / NM_001364857.2; = p.S1553L on NM_001294335.2) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs1424619746, COSV57077386; called by mutect2, varscan2
- ADGRB3 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV65413081; called by muse, mutect2, varscan2
- ADGRB3 | c.2098G>A p.G700R | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV65397875; called by muse, mutect2, varscan2
- ADGRD1 | c.2268-1G>A p.X756_splice | Splice Site (SNP) | VAF 8/23 reads (35%) | catalogued as COSV55453602; called by muse, mutect2, varscan2
- ADGRE1 | c.1990G>A p.G664S | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.433); catalogued as COSV51679479; called by muse, varscan2
- ADGRF1 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV99347205; called by muse, mutect2, varscan2
- ADGRF1 | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.868); catalogued as rs1302757729, COSV99347212; called by muse, mutect2, varscan2
- ADGRF5 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51938393; called by muse, mutect2, varscan2
- ADGRG4 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 107/122 reads (88%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs143735478, COSV54953456; called by muse, mutect2, varscan2
- ADGRG4 | c.8936G>A p.G2979E | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54963928; called by muse, varscan2
- ADGRL2 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.05); catalogued as COSV54682105; called by mutect2, varscan2
- ADGRL3 | c.2521C>T p.H841Y (on ENST00000506720 / NM_001322402.2; = p.H773Y on NM_015236.6) | Missense Mutation (SNP) | VAF 95/201 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101547262, COSV72231560; called by mutect2, varscan2
- ADGRL4 | c.1882G>A p.G628S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV100875948, COSV66064393; called by muse, mutect2, varscan2
- ADGRV1 | c.6778C>T p.R2260* | Nonsense Mutation (SNP) | VAF 9/13 reads (69%) | catalogued as rs779821643, COSV67977499; called by mutect2, varscan2
- ADGRV1 | c.9860C>T p.S3287L | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1169367531, COSV101315792, COSV101316496; called by mutect2, varscan2
- ADGRV1 | c.11660G>A p.G3887E | Missense Mutation (SNP) | VAF 49/63 reads (78%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs561320748, COSV67992711; called by muse, mutect2, varscan2
- ADGRV1 | c.16795C>T p.L5599F | Missense Mutation (SNP) | VAF 51/81 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV67992728; called by muse, mutect2, varscan2
- ADH1C | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV72624930; called by mutect2, varscan2
- ADH4 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1438535562, COSV55501948; called by muse, mutect2, varscan2
- ADH7 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.018); catalogued as COSV52922451; called by mutect2, varscan2
- ADH7 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52920943; called by muse, varscan2
- AFM | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as COSV56921568; called by muse, mutect2, varscan2
- AFP | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56926554; called by muse, mutect2, varscan2
- AGAP4 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1465936432; called by muse, varscan2
- AGBL1 | c.2405G>A p.R802Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs929491552, COSV66869099; called by mutect2, varscan2
- AGBL2 | c.2179G>A p.G727S | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1441799445, COSV54094640; called by muse, mutect2, varscan2
- AGGF1 | c.1896G>A p.W632* | Nonsense Mutation (SNP) | VAF 180/270 reads (67%) | catalogued as COSV57230741; called by muse, varscan2
- AGT | c.1270-1G>A p.X424_splice | Splice Site (SNP) | VAF 20/41 reads (49%) | catalogued as COSV100794326; called by muse, mutect2, varscan2
- AGXT | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV56755395; called by muse, mutect2, varscan2
- AGXT | c.777G>A p.M259I | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV56755404; called by muse, mutect2, varscan2
- AHCTF1 | c.1502C>T p.P501L (on ENST00000366508; = p.P475L on NM_015446.5) | Missense Mutation (SNP) | VAF 136/365 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV58253611; called by muse, mutect2, varscan2
- AHDC1 | c.3890C>T p.P1297L | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.199); catalogued as COSV55941410; called by muse, mutect2, varscan2
- AHDC1 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 84/219 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as COSV55941421; called by muse, mutect2, varscan2
- AHNAK | c.17345C>T p.S5782L | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs772135598, COSV57225359; called by mutect2, varscan2
- AHNAK | c.17159C>T p.S5720F | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57205006; called by muse, mutect2, varscan2
- AHNAK | c.5386A>T p.K1796* | Nonsense Mutation (SNP) | VAF 73/170 reads (43%) | catalogued as COSV57225378; called by muse, mutect2, varscan2
- AHNAK2 | c.7111C>T p.P2371S | Missense Mutation (SNP) | VAF 90/110 reads (82%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV60925488; called by muse, varscan2
- AHR | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.033); catalogued as rs190159217, COSV54121391; called by muse, mutect2, varscan2
- AHSG | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56608884; called by muse, mutect2
- AHSG | c.600G>C p.E200D | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56608890; called by muse, mutect2
- AK5 | c.828G>A p.M276I (on ENST00000354567 / NM_174858.3; = p.M250I on NM_012093.4) | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV60978913; called by mutect2, varscan2
- AK8 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV53758791; called by muse, mutect2, varscan2
- AKAP6 | c.4879G>A p.E1627K | Missense Mutation (SNP) | VAF 39/49 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1223003713, COSV55227331; called by muse, mutect2, varscan2
- AKAP8 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV54104048; called by muse, mutect2, varscan2
- AKAP9 | c.11206C>T p.R3736* (on ENST00000359028; = p.R3712* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/87 reads (22%) | catalogued as rs1234676587, COSV62354774; called by mutect2, varscan2
- AKNAD1 | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.027); catalogued as rs373934680; called by muse, mutect2, varscan2
- AKR1B10 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62055652, COSV62056289; called by muse, mutect2, varscan2
- AKR1C3 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65910981; called by muse, mutect2, varscan2
- AKR1D1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 66/116 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs866422324, COSV54339827; called by mutect2, varscan2
- AL121899.2 | c.625C>T p.L209F | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV67351989; called by muse, varscan2
- ALB | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV55741167; called by mutect2, varscan2
- ALB | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.28); catalogued as COSV55741177; called by muse, mutect2, varscan2
- ALCAM | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV60252874; called by muse, mutect2, varscan2
- ALG13 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV52643451; called by muse, mutect2, varscan2
- ALG8 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55202287; called by muse, varscan2
- ALG9 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs782761440, COSV67645172; called by muse, mutect2, varscan2
- ALK | c.4845G>A p.M1615I | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs747978928, COSV66584130; ClinVar: uncertain significance; called by mutect2, varscan2
- ALK | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 63/118 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV66564584, COSV66584134; called by muse, mutect2, varscan2
- ALKBH2 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs1159049040, COSV54358385; called by muse, mutect2, varscan2
- ALLC | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52997407; called by muse, mutect2, varscan2
- ALPK2 | c.5285A>C p.E1762A | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as COSV100864311; called by muse, mutect2, varscan2
- ALPK2 | c.5284G>A p.E1762K | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as rs898482941, COSV64490476; called by mutect2, varscan2
- ALS2CL | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV59673070; called by muse, mutect2, varscan2
- AMHR2 | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV57686632; called by muse, mutect2, varscan2
- AMPD1 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.85); PolyPhen benign (0.125); catalogued as COSV62417990; called by muse, mutect2, varscan2
- AMPD1 | c.1655G>A p.S552N | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV62418005; called by muse, mutect2, varscan2
- AMPD3 | c.574G>A p.E192K (on ENST00000396553 / NM_001025389.2; = p.E201K on NM_000480.3) | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV67332009; called by muse, mutect2, varscan2
- AMPD3 | c.877G>A p.E293K (on ENST00000396553 / NM_001025389.2; = p.E302K on NM_000480.3) | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs760590808, COSV67331501; called by mutect2, varscan2
- AMPH | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs761049841, COSV57731874; called by muse, mutect2, varscan2
- ANAPC1 | c.5308C>T p.L1770F | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV61974308, COSV61978513; called by muse, mutect2, varscan2
- ANAPC5 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 152/435 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.271); catalogued as rs782361863, COSV55844550, COSV99946442; called by muse, mutect2, varscan2
- ANK1 | c.3203G>A p.R1068Q | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs763961763, COSV55891497, COSV99223905; called by muse, mutect2, varscan2
- ANK3 | c.10108G>A p.E3370K | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as COSV55074961; called by mutect2, varscan2
- ANK3 | c.7957G>A p.G2653S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.237); catalogued as COSV55074985; called by muse, varscan2
- ANK3 | c.6532C>T p.P2178S | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55049573; called by muse, mutect2, varscan2
- ANK3 | c.5618C>T p.S1873L | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV55075002; called by mutect2, varscan2
- ANK3 | c.2758G>A p.D920N (on ENST00000280772 / NM_001320874.2; = p.D54N on NM_001149.3) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1378776980, COSV55075016; called by muse, varscan2
- ANK3 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55075083; called by mutect2, varscan2
- ANKIB1 | c.2944C>T p.P982S | Missense Mutation (SNP) | VAF 54/93 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56064912; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 106/418 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV62007153; called by muse, varscan2
- ANKRD24 | c.3363G>A p.Q1121= | Splice Region (SNP) | VAF 7/22 reads (32%) | catalogued as COSV53674510; called by muse, mutect2, varscan2
- ANKRD30A | c.553G>A p.E185K (on ENST00000611781; = p.E129K on NM_052997.2) | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV64617562; called by mutect2, varscan2
- ANKRD30A | c.2512+2T>A p.X838_splice (on ENST00000611781; = p.X782_splice on NM_052997.2) | Splice Site (SNP) | VAF 36/118 reads (31%) | catalogued as COSV64617580; called by mutect2, varscan2
- ANKRD33 | c.728G>A p.G243E (on ENST00000340970 / NM_001304459.2; = p.E435K on NM_182608.4) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as COSV56607881; called by muse, mutect2, varscan2
- ANKS3 | c.118C>T p.H40Y | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.426); catalogued as rs200097253, COSV54794464; called by mutect2, varscan2
- ANKS4B | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV61140042, COSV61140314; called by muse, mutect2, varscan2
- ANO3 | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV56802031, COSV56803453; called by muse, mutect2, varscan2
- ANO7 | c.1874G>A p.G625E (on ENST00000274979; = p.G571E on NM_001370694.2) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779097306, COSV51477043; called by muse, mutect2, varscan2
- ANP32A | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV51189834; called by muse, mutect2, varscan2
- ANPEP | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs376358699, COSV100263637; called by muse, mutect2, varscan2
- ANXA1 | c.893G>A p.R298K | Missense Mutation (SNP) | VAF 128/156 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV57412317; called by muse, varscan2
- ANXA13 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as rs777956701, COSV51624134; called by muse, mutect2, varscan2
- AOAH | c.971G>A p.W324* | Nonsense Mutation (SNP) | VAF 47/166 reads (28%) | catalogued as COSV51735711; called by muse, mutect2, varscan2
- AOAH | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.259); catalogued as rs759933828, COSV51748365; called by muse, mutect2, varscan2
- AOC2 | c.2249C>T p.P750L (on ENST00000253799 / NM_009590.4; = p.P723L on NM_001158.5) | Missense Mutation (SNP) | VAF 96/133 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV53828254; called by muse, mutect2, varscan2
- AP002512.3 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.864); catalogued as COSV54408241; called by muse, mutect2, varscan2
- AP1B1 | c.2155C>T p.P719S | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as COSV58022042; called by muse, mutect2, varscan2
- AP3S1 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.323); catalogued as COSV57476562; called by muse, varscan2
- APC2 | c.2575G>A p.E859K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs752199141, COSV52021119; called by muse, mutect2, varscan2
- APOB | c.2633C>T p.S878F | Missense Mutation (SNP) | VAF 191/387 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51947467; called by muse, mutect2, varscan2
- APOBEC3H | c.246G>A p.W82* | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as rs1194362605, COSV62379045; called by muse, mutect2, varscan2
- APOF | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1422902992, COSV58476282; called by muse, mutect2, varscan2
- ARAP1 | c.2963C>T p.S988F (on ENST00000393609 / NM_001040118.2; = p.S743F on NM_015242.4) | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as COSV61993859; called by muse, mutect2, varscan2
- ARAP2 | c.2638C>T p.H880Y | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58287269; called by mutect2, varscan2
- ARAP2 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs551766032, COSV58290634; called by mutect2, varscan2
- ARAP3 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV53353523; called by muse, mutect2, varscan2
- ARHGAP10 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV60604335; called by muse, mutect2, varscan2
- ARHGAP21 | c.5261C>T p.S1754F | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.251); catalogued as COSV57609767; called by muse, mutect2, varscan2
- ARHGAP22 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50967170; called by muse, mutect2
- ARHGAP29 | c.2072G>A p.C691Y | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53115421; called by mutect2, varscan2
- ARHGAP32 | c.3052C>T p.P1018S (on ENST00000310343 / NM_001378025.1; = p.P669S on NM_014715.4) | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.02); catalogued as rs200876570, COSV59853538; called by muse, mutect2, varscan2
- ARHGAP32 | c.2645C>T p.S882F (on ENST00000310343 / NM_001378025.1; = p.S533F on NM_014715.4) | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV59853551; called by muse, mutect2, varscan2
- ARHGAP32 | c.1906C>T p.H636Y (on ENST00000310343 / NM_001378025.1; = p.H287Y on NM_014715.4) | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV59853573; called by mutect2, varscan2
- ARHGAP33 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.306); catalogued as COSV50144624; called by muse, mutect2, varscan2
- ARHGEF11 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV100809989; called by muse, mutect2, varscan2
- ARHGEF19 | c.2110C>T p.P704S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV54618055; called by muse, mutect2, varscan2
- ARHGEF4 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV58126037; called by muse, mutect2, varscan2
- ARID5A | c.1304T>C p.F435S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.081); catalogued as COSV62591636; called by muse, mutect2, varscan2
- ARMC12 | c.833C>T p.S278F (on ENST00000373866 / NM_001286574.2; = p.S305F on NM_145028.5) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55361292; called by muse, mutect2, varscan2
- ARMC2 | c.1225G>T p.G409* | Nonsense Mutation (SNP) | VAF 27/72 reads (38%) | catalogued as COSV104426194, COSV64550039; called by mutect2, varscan2
- ASB17 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV52409524; called by muse, mutect2, varscan2
- ASH1L | c.4232C>T p.P1411L | Missense Mutation (SNP) | VAF 48/79 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV64212132; called by muse, mutect2, varscan2
- ASH1L | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 83/175 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.113); catalogued as COSV100853364; called by muse, mutect2, varscan2
- ASH1L | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 83/174 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); catalogued as COSV100853365; called by muse, mutect2, varscan2
- ASTN1 | c.2481G>A p.Q827= | Splice Region (SNP) | VAF 12/55 reads (22%) | catalogued as COSV56079840; called by muse, mutect2, varscan2
- ASTN1 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 198/353 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs866639170, COSV56061286; called by muse, mutect2, varscan2
- ASXL1 | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 128/199 reads (64%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.887); catalogued as rs769594900, COSV60117384, COSV60123243; called by muse, mutect2, varscan2
- ASXL3 | c.729G>A p.W243* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV52480344, COSV99324581; called by muse, mutect2, varscan2
- ASXL3 | c.3574C>T p.P1192S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as rs1438569915, COSV52456412; called by muse, mutect2, varscan2
- ASXL3 | c.3958G>A p.D1320N | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs867039549, COSV52475488; called by muse, mutect2, varscan2
- ASZ1 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 72/84 reads (86%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.451); catalogued as rs1164227758, COSV52915439; called by muse, mutect2, varscan2
- ATAD2B | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.335); catalogued as rs774687507, COSV53198053, COSV53198198; called by muse, mutect2, varscan2
- ATCAY | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56658231; called by muse, varscan2
- ATF4 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.184); catalogued as COSV57480275; called by muse, mutect2, varscan2
- ATG9A | c.1161C>G p.I387M | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV63446384; called by muse, mutect2, varscan2
- ATL1 | c.1492G>A p.G498R | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63297277; called by muse, mutect2, varscan2
- ATN1 | c.2555C>T p.P852L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as rs781912725, COSV63110897, COSV63112572; called by muse, mutect2, varscan2
- ATP10A | c.4325C>T p.S1442F | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as COSV63513953; called by muse, mutect2, varscan2
- ATP13A3 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV55464153; called by mutect2, varscan2
- ATP1A1 | c.937C>T p.L313F | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV55190176, COSV55193464; called by muse, mutect2, varscan2
- ATP1A2 | c.2015C>T p.S672L | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs145701604; ClinVar: uncertain significance / likely benign; called by mutect2, varscan2
- ATP1A3 | c.2263G>A p.D755N (on ENST00000545399 / NM_001256214.2; = p.D742N on NM_152296.5) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.421); catalogued as COSV57490295; called by muse, mutect2, varscan2
- ATP2A1 | c.2459C>T p.P820L | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.121); catalogued as COSV100706965; called by muse, mutect2, varscan2
- ATP4A | c.2179G>A p.G727R | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749693841, COSV52870799; called by muse, mutect2, varscan2
- ATP7B | c.3956G>A p.R1319Q | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as rs529307157, COSV54442102; called by mutect2, varscan2
- ATP8B3 | c.3467T>A p.I1156N | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.454); catalogued as COSV59547014; called by muse, mutect2, varscan2
- ATP8B4 | c.2164G>A p.G722R | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.03); catalogued as COSV52721754; called by muse, mutect2, varscan2
- ATP8B4 | c.1813G>A p.D605N | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV52721762; called by mutect2, varscan2
- ATP8B4 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748152515, COSV52717553; called by muse, mutect2, varscan2
- ATRNL1 | c.2426C>T p.P809L | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58106730; called by muse, mutect2, varscan2
- ATXN7L2 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT tolerated (0.61); PolyPhen benign (0.119); catalogued as COSV63992810; called by muse, mutect2, varscan2
- B3GALNT1 | c.989A>G p.H330R | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs947016041, COSV57581000; called by muse, mutect2, varscan2
- B3GNT7 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55007354; called by muse, mutect2, varscan2
- B4GALNT2 | c.1607A>G p.K536R | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV55927746; called by muse, mutect2
- BABAM1 | c.901C>T p.H301Y | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV63921441; called by mutect2, varscan2
- BAHD1 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV101346751; called by muse, mutect2, varscan2
- BAHD1 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs758887263, COSV101346752; called by muse, mutect2, varscan2
- BAIAP2L1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50059007; called by mutect2, varscan2
- BAIAP3 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1451373374, COSV60982963; called by muse, mutect2, varscan2
- BAIAP3 | c.3241G>A p.E1081K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs567104517, COSV50104889; called by mutect2, varscan2
- BANK1 | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59847888; called by muse, mutect2, varscan2
- BANK1 | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 73/182 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59847897; called by muse, mutect2, varscan2
- BAZ1A | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 61/67 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62411750; called by muse, mutect2, varscan2
- BCAS3 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 78/92 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV66779801; called by muse, varscan2
- BCAT1 | c.965G>A p.G322E | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53915744; called by muse, mutect2, varscan2
- BCL2L12 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV55864122, COSV55864293; called by muse, mutect2, varscan2
- BCL2L14 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV53792229; called by mutect2, varscan2
- BCL6B | c.1124G>A p.S375N | Missense Mutation (SNP) | VAF 51/60 reads (85%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV53429111, COSV53430404; called by muse, varscan2
- BCL9 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV52348747; called by muse, mutect2, varscan2
- BCL9 | c.598A>G p.I200V | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs139276872; called by muse, mutect2, varscan2
- BCL9 | c.1931C>T p.P644L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as COSV52348770; called by muse, mutect2, varscan2
- BCO2 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63064472; called by muse, mutect2, varscan2
- BCOR | c.3301C>T p.P1101S | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100653197; called by muse, mutect2, varscan2
- BDNF | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.936); catalogued as COSV100151420; called by muse, mutect2, varscan2
- BDNF | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.988); catalogued as COSV100151423; called by mutect2, varscan2
- BDP1 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62433487; called by muse, mutect2, varscan2
- BEST4 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1248600356, COSV64734368; called by muse, mutect2, varscan2
- BIN2 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.015); catalogued as COSV57207312; called by muse, mutect2, varscan2
- BLNK | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV56414008; called by mutect2, varscan2
- BMP10 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs867162659, COSV54896542; called by muse, mutect2, varscan2
- BMPER | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.91); catalogued as COSV51827979; called by mutect2, varscan2
- BMS1 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 39/73 reads (53%) | catalogued as COSV65735019; called by muse, mutect2, varscan2
- BNC1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV61757116, COSV61758705; called by mutect2, varscan2
- BNIP5 | c.134G>A p.R45K | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as COSV71325783; called by muse, mutect2, varscan2
- BPIFC | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 32/66 reads (48%) | catalogued as COSV55915019; called by mutect2, varscan2
- BRD2 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV66374284; called by muse, mutect2, varscan2
- BRD4 | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs1568388201, COSV54592098; called by muse, mutect2, varscan2
- BRD9 | c.1669T>A p.S557T | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV60249097; called by muse, varscan2
- BRINP3 | c.1983G>A p.M661I | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV66528270; called by muse, mutect2, varscan2
- BSN | c.7031G>A p.G2344D | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV56525014; called by muse, mutect2, varscan2
- BSN | c.10645C>T p.R3549W | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776200643, COSV56514040; called by mutect2, varscan2
- BTBD11 | c.3175G>A p.E1059K (on ENST00000280758 / NM_001018072.2; = p.E596K on NM_001017523.2) | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV55033516; called by muse, mutect2, varscan2
- BTG2 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1413642682, COSV51857200, COSV51858153; called by mutect2, varscan2
- BTNL8 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 87/115 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs549440974, COSV51460733; called by mutect2, varscan2
- BTNL8 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 112/152 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV51460749; called by muse, mutect2, varscan2
- BUB1B | c.2110C>T p.P704S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.041); catalogued as rs866257980, COSV55015577; called by muse, mutect2, varscan2
- C14orf39 | c.1721T>A p.F574Y | Missense Mutation (SNP) | VAF 172/217 reads (79%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV58784192; called by muse, mutect2, varscan2
- C18orf54 | c.910C>A p.L304I | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55618994; called by muse, varscan2
- C19orf18 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1266990636, COSV58707582; called by muse, mutect2, varscan2
- C19orf57 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60969765; called by muse, mutect2, varscan2
- C1QTNF9B | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs765374311, COSV65944486; called by muse, mutect2, varscan2
- C1orf112 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV53681603, COSV99609668; called by muse, mutect2, varscan2
- C1orf127 | c.1906G>A p.G636R | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV65438484; called by muse, mutect2, varscan2
- C1orf131 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as rs779405167, COSV59642948; called by muse, mutect2, varscan2
- C3orf20 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV53785637; called by muse, varscan2
- C3orf20 | c.667T>G p.Y223D | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53788204; called by muse, mutect2, varscan2
- C4B | c.3347C>T p.S1116L | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs767540386, COSV70313250; called by mutect2, varscan2
- C4BPA | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.101); catalogued as COSV65537251; called by muse, mutect2, varscan2
- C5AR1 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs953889963, COSV100754008; called by muse, mutect2, varscan2
- C6 | c.888T>A p.N296K | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs1561136805, COSV54715716; called by muse, mutect2, varscan2
- C6 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as rs201513771, COSV54715726, COSV99666738; called by muse, varscan2
- C6 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 91/251 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54712314; called by muse, mutect2, varscan2
- C7 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as rs753530114, COSV57477052; called by mutect2, varscan2
- C8B | c.952C>T p.L318F | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.16); catalogued as COSV64777744; called by muse, mutect2, varscan2
- C8B | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.047); catalogued as rs747849141, COSV64778975; called by muse, mutect2, varscan2
- C9orf64 | c.878T>C p.L293P | Missense Mutation (SNP) | VAF 74/83 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59032970; called by muse, mutect2, varscan2
- CA13 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58798813; called by muse, mutect2, varscan2
- CA8 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs201131573, COSV58771470; called by mutect2, varscan2
- CABCOCO1 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV57593145; called by muse, varscan2
- CABP2 | c.326C>T p.T109I | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1185147211, COSV53709484; called by muse, varscan2
- CABP5 | c.173G>A p.R58K | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV53153692, COSV99506511; called by muse, varscan2
- CACNA1C | c.2747C>T p.S916F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs866162457, COSV59708199; called by muse, mutect2, varscan2
- CACNA1E | c.375G>A p.E125= | Splice Region (SNP) | VAF 120/236 reads (51%) | catalogued as COSV62386054, COSV62417372; called by muse, mutect2, varscan2
- CACNA1G | c.3628C>T p.R1210W | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as rs772770633, COSV100661714, COSV61742822; called by muse, mutect2, varscan2
- CACNA1H | c.4723G>A p.E1575K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs750349354, COSV62000188; called by mutect2, varscan2
- CACNA1I | c.1072G>A p.G358S | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60800070; called by muse, mutect2
- CACNA1S | c.261G>A p.E87= | Splice Region (SNP) | VAF 34/54 reads (63%) | catalogued as COSV62942526; called by muse, mutect2, varscan2
- CACNA2D1 | c.2635G>A p.D879N (on ENST00000356253 / NM_001366867.1; = p.D867N on NM_000722.4) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV62377681; called by mutect2, varscan2
- CACNA2D3 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs552100021, COSV55568277; called by muse, mutect2, varscan2
- CACNA2D3 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.574); catalogued as COSV55568290; called by muse, mutect2, varscan2
- CACNB2 | c.161G>A p.G54E (on ENST00000324631 / NM_201596.3; = p.G26E on NM_201571.4) | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.441); catalogued as COSV56640169; called by muse, mutect2, varscan2
- CACNG3 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV50069569; called by muse, mutect2, varscan2
- CACNG5 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 50/64 reads (78%) | SIFT tolerated (0.66); PolyPhen benign (0.285); catalogued as COSV50057402; called by muse, varscan2
- CADM2 | c.1018A>C p.I340L (on ENST00000407528 / NM_001167674.2; = p.I342L on NM_153184.4) | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV67395279; called by muse, mutect2, varscan2
- CADM2 | c.1238C>T p.A413V (on ENST00000407528 / NM_001167674.2; = p.A415V on NM_153184.4) | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67388932; called by muse, mutect2, varscan2
- CADM3 | c.1127C>T p.A376V (on ENST00000368125 / NM_001127173.3; = p.A410V on NM_021189.5) | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761014332, COSV63674136; called by muse, mutect2, varscan2
- CADM4 | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 43/82 reads (52%) | catalogued as COSV55929600; called by muse, mutect2, varscan2
- CADPS | c.2434G>A p.A812T | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV51895909; called by muse, mutect2, varscan2
- CALCRL | c.1328G>A p.G443E | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV66476639; called by muse, mutect2, varscan2
- CALCRL | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.085); catalogued as COSV66476646; called by muse, mutect2, varscan2
- CALHM5 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62068303; called by muse, mutect2, varscan2
- CALHM6 | c.728G>A p.G243D | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.289); catalogued as COSV63991704; called by muse, mutect2, varscan2
- CAMK2B | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.71); PolyPhen possibly damaging (0.738); catalogued as COSV51664711; called by muse, mutect2, varscan2
- CAMSAP1 | c.3409C>T p.P1137S | Missense Mutation (SNP) | VAF 57/71 reads (80%) | SIFT tolerated (0.58); PolyPhen benign (0.058); catalogued as rs771843413, COSV56726712; called by muse, mutect2, varscan2
- CAMSAP3 | c.3406G>A p.G1136S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50348656; called by muse, mutect2, varscan2
- CAMTA1 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57887236, COSV57906544; called by mutect2, varscan2
- CAMTA2 | c.2626A>G p.M876V | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV52778842; called by muse, mutect2, varscan2
- CAPN11 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.191); catalogued as COSV67237856; called by muse, mutect2, varscan2
- CAPN13 | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV54434128; called by muse, mutect2, varscan2
- CAPN6 | c.1292A>G p.N431S | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60696590; called by muse, mutect2, varscan2
- CAPN7 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53779038; called by muse, mutect2, varscan2
- CARD10 | c.392G>A p.G131D | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99324872; called by muse, mutect2, varscan2
- CARD11 | c.2706C>T p.F902= | Splice Region (SNP) | VAF 12/28 reads (43%) | catalogued as rs372346149; called by mutect2, varscan2
- CARD11 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs755527825, COSV62754337; called by mutect2, varscan2
- CARMIL1 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV61522279; called by muse, mutect2, varscan2
- CASP10 | c.1274C>T p.S425F (on ENST00000272879 / NM_032974.5; = p.S382F on NM_001230.5) | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as rs772629649, COSV53780000; called by muse, mutect2, varscan2
- CASQ1 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 82/122 reads (67%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs138808242; called by mutect2, varscan2
- CASQ1 | c.597T>G p.D199E | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV63624439; called by muse, mutect2, varscan2
- CASR | c.2009C>T p.P670L (on ENST00000490131; = p.P747L on NM_000388.4) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM165802, COSV56140360; called by muse, mutect2, varscan2
- CASS4 | c.1004T>A p.F335Y | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV64387899; called by mutect2, varscan2
- CASZ1 | c.2821G>A p.E941K | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs778342496, COSV59739805; called by mutect2, varscan2
- CATIP | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56824048; called by muse, mutect2, varscan2
- CATIP | c.921G>T p.K307N | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99179528; called by muse, mutect2, varscan2
- CATSPERB | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 90/111 reads (81%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs139686935; called by muse, mutect2, varscan2
- CBLC | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 59/119 reads (50%) | catalogued as COSV54325001; called by mutect2, varscan2
- CCDC102B | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as rs1286520360, COSV60150718; called by mutect2, varscan2
- CCDC110 | c.440G>A p.S147N | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.162); catalogued as COSV56872879; called by muse, mutect2, varscan2
- CCDC116 | c.1094C>T p.S365F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as rs1280419862, COSV53042029; called by muse, mutect2, varscan2
- CCDC138 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV51706303; called by muse, mutect2
- CCDC141 | c.4123C>T p.Q1375* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV55369542; called by mutect2, varscan2
- CCDC141 | c.3703G>A p.E1235K | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1005901240, COSV55379661; called by muse, mutect2, varscan2
- CCDC141 | c.3301C>T p.L1101F | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV55371878, COSV55381669; called by muse, mutect2, varscan2
- CCDC144A | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.4); PolyPhen benign (0.438); catalogued as rs1307939550; called by muse, mutect2, varscan2
- CCDC149 | c.844C>T p.H282Y | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.687); catalogued as COSV60881193; called by mutect2, varscan2
- CCDC158 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 33/83 reads (40%) | catalogued as rs372653725; called by mutect2, varscan2
- CCDC158 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.99); catalogued as COSV66356906; called by mutect2, varscan2
- CCDC172 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as COSV100319840, COSV60939594; called by muse, varscan2
- CCDC185 | c.1424G>A p.R475K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.038); catalogued as COSV64821599; called by muse, varscan2
- CCDC185 | c.1714G>A p.V572M | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64821602; called by muse, mutect2, varscan2
- CCDC191 | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as rs575617276, COSV55675151; called by muse, mutect2, varscan2
- CCDC83 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.41); catalogued as COSV54703477; called by muse, mutect2, varscan2
- CCDC88C | c.2891A>T p.N964I | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV66240622; called by muse, mutect2, varscan2
- CCDC93 | c.1426C>T p.R476* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as rs770401792, COSV60123381; called by mutect2, varscan2
- CCK | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58184306; called by muse, mutect2, varscan2
- CCM2L | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52951946; called by mutect2, varscan2
- CCNA1 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1238091930, COSV55222501; called by muse, mutect2, varscan2
- CCR9 | c.664G>A p.G222R (on ENST00000357632 / NM_031200.3; = p.G210R on NM_006641.4) | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV62940632; called by muse, mutect2, varscan2
- CCRL2 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 99/266 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as COSV62193624, COSV62193982; called by muse, mutect2, varscan2
- CCT2 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.364); catalogued as COSV54741152; called by muse, mutect2, varscan2
- CD101 | c.2837C>T p.P946L | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56720136; called by muse, mutect2, varscan2
- CD109 | c.1688G>A p.W563* | Nonsense Mutation (SNP) | VAF 31/70 reads (44%) | catalogued as COSV99753395; called by mutect2, varscan2
- CD109 | c.1689G>A p.W563* | Nonsense Mutation (SNP) | VAF 32/72 reads (44%) | catalogued as COSV99753399, COSV99753861; called by muse, mutect2, varscan2
- CD163 | c.1879G>A p.G627R | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63136129; called by muse, mutect2, varscan2
- CD163L1 | c.1673G>A p.S558N | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV58022465; called by muse, mutect2, varscan2
- CD163L1 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.114); catalogued as rs779319847, COSV58022471; called by muse, mutect2, varscan2
- CD1C | c.880C>T p.L294F | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs780763972, COSV63806482; called by muse, mutect2, varscan2
- CD2 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV65643710; called by muse, mutect2, varscan2
- CD22 | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.193); catalogued as rs745341857, COSV99323128; called by muse, mutect2, varscan2
- CD244 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.631); catalogued as COSV59240494; called by mutect2, varscan2
- CD53 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54762425; called by muse, mutect2, varscan2
- CD5L | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs774041523, COSV63822811; called by muse, mutect2, varscan2
- CD5L | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 97/191 reads (51%) | SIFT tolerated (0.61); PolyPhen benign (0.076); catalogued as COSV63821273; called by muse, mutect2, varscan2
- CD5L | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 94/184 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as rs200131192, COSV63821183, COSV63822864; called by mutect2, varscan2
- CDC42BPA | c.4991C>T p.S1664F (on ENST00000334218 / NM_001366019.2; = p.S1651F on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV62017778; called by muse, mutect2, varscan2
- CDC42BPB | c.5071C>T p.P1691S | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54487571; called by muse, mutect2, varscan2
- CDH1 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.244); catalogued as COSV55738577; called by muse, mutect2
- CDH12 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66396706, COSV66440665; called by muse, mutect2, varscan2
- CDH12 | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101203218, COSV66392701; called by muse, mutect2, varscan2
- CDH13 | c.208A>G p.S70G | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.099); catalogued as COSV51855864; called by muse, mutect2, varscan2
- CDH2 | c.1652G>A p.G551E | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52286426; called by muse, mutect2, varscan2
- CDH2 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as rs150313483; called by mutect2, varscan2
- CDH20 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as rs758510987, COSV53004764, COSV53005466; called by muse, mutect2, varscan2
- CDH23 | c.5384C>T p.S1795F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56482182; called by muse, mutect2, varscan2
- CDH26 | c.1555C>T p.H519Y | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as COSV54852074; called by muse, varscan2
- CDH4 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV64669269; called by muse, varscan2
- CDH5 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774948104, COSV58519281; called by mutect2, varscan2
- CDH6 | c.1109T>C p.V370A | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54075921; called by muse, mutect2, varscan2
- CDH8 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV100181039; called by mutect2, varscan2
- CDH9 | c.2317C>T p.R773C | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs568693690, COSV50256740, COSV50269687; called by mutect2, varscan2
- CDH9 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV50272964, COSV50386379; called by mutect2, varscan2
- CDH9 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV50386790; called by muse, varscan2
- CDH9 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 85/211 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as rs531958842, COSV50256671, COSV99162875; called by muse, mutect2, varscan2
- CDHR2 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV56143431; called by muse, mutect2, varscan2
- CDHR2 | c.768+1G>A p.X256_splice | Splice Site (SNP) | VAF 16/28 reads (57%) | catalogued as COSV56143437; called by muse, mutect2, varscan2
- CDHR5 | c.1957G>A p.E653K (on ENST00000358353 / NM_001171968.2; = p.E659K on NM_021924.5) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.636); catalogued as COSV100363857, COSV57645384; called by muse, mutect2, varscan2
- CDON | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs756707042, COSV55004442; called by mutect2, varscan2
- CEACAM19 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 221/502 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV100715440; called by muse, mutect2, varscan2
- CEACAM20 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 104/259 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV57602823; called by muse, mutect2, varscan2
- CEACAM7 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.169); catalogued as COSV50074111; called by muse, mutect2, varscan2
- CECR2 | c.2809C>T p.P937S (on ENST00000342247 / NM_001290047.2; = p.P754S on NM_001290046.1) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.991); catalogued as rs1236274713, COSV52846171; called by muse, varscan2
- CEL | c.1751C>T p.P584L (on ENST00000673714; = p.P581L on NM_001807.6) | Missense Mutation (SNP) | VAF 44/50 reads (88%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV60829055; called by muse, varscan2
- CELA3B | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 123/243 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV61404060; called by muse, mutect2, varscan2
- CEMIP | c.3727G>A p.E1243K | Missense Mutation (SNP) | VAF 69/167 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.272); catalogued as COSV54998270; called by muse, mutect2, varscan2
- CES3 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.402); catalogued as COSV57594875; called by muse, mutect2, varscan2
- CFAP100 | c.1239G>C p.K413N | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV61504178; called by muse, mutect2, varscan2
- CFAP300 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as rs140641107; called by mutect2, varscan2
- CFAP43 | c.1978G>A p.G660R | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53380337; called by muse, mutect2, varscan2
- CFAP44 | c.2518C>T p.P840S | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as COSV55614726; called by muse, mutect2, varscan2
- CFAP46 | c.361G>T p.G121* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV63953662; called by muse, mutect2, varscan2
- CFAP54 | c.5611G>A p.D1871N | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV61574277; called by muse, mutect2, varscan2
- CFAP54 | c.5768C>T p.S1923L | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV61574281; called by muse, mutect2, varscan2
- CFAP54 | c.6133C>T p.Q2045* | Nonsense Mutation (SNP) | VAF 43/105 reads (41%) | catalogued as COSV61573954, COSV61574285; called by mutect2, varscan2
- CFAP65 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1223042898, COSV55390429; called by muse, varscan2
- CFAP65 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV55391518; called by muse, varscan2
- CFAP69 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 61/128 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV60187571; called by mutect2, varscan2
- CFAP74 | c.1376G>A p.W459* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as COSV54572196; called by muse, mutect2, varscan2
- CFAP91 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV56342652, COSV56343156; called by muse, mutect2, varscan2
- CFAP91 | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 74/145 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267599558, COSV56340073; called by muse, mutect2, varscan2
- CFH | c.1852C>T p.P618S | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100809468, COSV66411741; called by muse, mutect2, varscan2
- CFHR4 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 58/91 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV52228832; called by muse, mutect2, varscan2
- CFTR | c.1726G>A p.G576R | Missense Mutation (SNP) | VAF 94/188 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as CM962466, COSV50082902; called by muse, mutect2, varscan2
- CGAS | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as COSV64807804; called by muse, mutect2, varscan2
- CHD2 | c.4733C>T p.P1578L | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV67713186; called by muse, mutect2, varscan2
- CHD2 | c.5362C>T p.R1788C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as rs759259416, COSV67707794; called by mutect2, varscan2
- CHD6 | c.3336G>A p.W1112* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV58560844; called by muse, mutect2
- CHML | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.067); catalogued as rs755671388, COSV59366569; called by muse, mutect2, varscan2
- CHRDL2 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV55224507; called by muse, mutect2, varscan2
- CHRDL2 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55222961; called by muse, mutect2, varscan2
- CHRFAM7A | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100241572; called by mutect2, varscan2
- CHRM2 | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 59/95 reads (62%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs142493466; called by muse, mutect2, varscan2
- CHRM3 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55098720, COSV99698736; called by mutect2, varscan2
- CHRNB3 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51496982; called by muse, mutect2, varscan2
- CHRND | c.873C>G p.F291L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51327357; called by muse, mutect2, varscan2
- CHST15 | c.292C>T p.L98F | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100655074; called by muse, mutect2, varscan2
- CHST6 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as COSV60001310; called by muse, mutect2, varscan2
- CHUK | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as COSV100957081; called by mutect2, varscan2
- CIB2 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs768296462, COSV51949626; called by muse, mutect2, varscan2
- CIB3 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as rs752378532, COSV54166105; called by mutect2, varscan2
- CIDEA | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs749641132, COSV57600041; called by muse, mutect2, varscan2
- CILP2 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV52278887; called by muse, mutect2, varscan2
- CILP2 | c.1115C>T p.T372I | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as rs770838972, COSV52278897; called by muse, mutect2, varscan2
- CKAP2L | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs372868873; called by muse, mutect2, varscan2
- CKM | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV55534723; called by muse, mutect2, varscan2
- CLASP1 | c.1907C>T p.S636F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55335131; called by muse, mutect2, varscan2
- CLCA4 | c.1541G>A p.G514E | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1362838003, COSV55366493; called by muse, varscan2
- CLCA4 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1291579484, COSV55370206; called by muse, mutect2, varscan2
- CLCA4 | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as COSV65284473, COSV65284732; called by mutect2, varscan2
- CLCN1 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.834); catalogued as COSV58373290; called by muse, mutect2, varscan2
- CLDN1 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99790572; called by muse, mutect2, varscan2
- CLDN19 | c.536G>A p.G179D | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1217588010, COSV56418667; called by muse, mutect2, varscan2
- CLDN9 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1388025205, COSV60911440; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLEC1A | c.822A>C p.E274D | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV59533542; called by muse, mutect2, varscan2
- CLEC3A | c.355G>A p.E119K (on ENST00000651443; = p.E110K on NM_005752.6) | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs202038528, COSV55219665, COSV55219802, COSV55220651; called by muse, mutect2, varscan2
- CLEC4C | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as COSV63582992; called by mutect2, varscan2
- CLEC4F | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55477994; called by muse, mutect2, varscan2
- CLEC5A | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.049); catalogued as COSV69397878; called by mutect2, varscan2
- CLGN | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.297); catalogued as COSV57775963; called by muse, mutect2, varscan2
- CLIP4 | c.1591G>A p.G531R | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV60751581; called by muse, mutect2, varscan2
- CLSTN2 | c.2222C>T p.S741F | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV71723841; called by muse, mutect2, varscan2
- CLVS1 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.566); catalogued as COSV57980795; called by muse, mutect2, varscan2
- CMYA5 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV71408623; called by muse, mutect2, varscan2
- CNGA1 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV62056074; called by muse, mutect2, varscan2
- CNGA3 | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as CM152788, COSV55627056; called by muse, mutect2, varscan2
- CNKSR3 | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1227092000, COSV101401341; called by muse, mutect2, varscan2
- CNOT1 | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV57777499; called by muse, mutect2, varscan2
- CNPY1 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV58788138; called by muse, mutect2, varscan2
- CNTN1 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as COSV61637726; called by muse, mutect2, varscan2
- CNTN1 | c.1251G>A p.M417I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs145510600, COSV61643848; called by mutect2, varscan2
- CNTN4 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68586587; called by muse, mutect2, varscan2
- CNTN4 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1018920181, COSV61867465; called by muse, mutect2, varscan2
- CNTN4 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.195); catalogued as COSV61878503; called by mutect2, varscan2
- CNTN4 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.405); catalogued as COSV61869995; called by mutect2, varscan2
- CNTN5 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.05); catalogued as rs777437500, COSV54343863, COSV54359917, COSV99682022; called by muse, mutect2, varscan2
- CNTN5 | c.1732C>T p.P578S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54343901; called by muse, varscan2
- CNTN5 | c.2573G>A p.G858E | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs867933506, COSV54343942; called by muse, varscan2
- CNTN6 | c.2166+1G>A p.X722_splice | Splice Site (SNP) | VAF 34/86 reads (40%) | catalogued as COSV63184499, COSV63193415; called by muse, varscan2
- CNTNAP4 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as rs1014910351, COSV56669618; called by muse, mutect2, varscan2
- CNTNAP4 | c.2138G>A p.G713E | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV56695004; called by muse, mutect2, varscan2
- CNTNAP5 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70494492; called by muse, mutect2
- COBLL1 | c.3185C>T p.S1062L (on ENST00000392717; = p.S1024L on NM_014900.5) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1325995096, COSV52074142; called by mutect2, varscan2
- COBLL1 | c.2450C>T p.S817F (on ENST00000392717; = p.S779F on NM_014900.5) | Missense Mutation (SNP) | VAF 73/127 reads (57%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.795); catalogued as COSV52074164; called by muse, mutect2, varscan2
- COL11A1 | c.2104C>T p.P702S | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs866684077, COSV62173442; called by muse, varscan2
- COL11A1 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as COSV62185129, COSV62195592; called by muse, mutect2, varscan2
- COL11A2 | c.4207G>A p.D1403N (on ENST00000341947 / NM_080680.3; = p.D1296N on NM_080679.2) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs1010102698, COSV59497274; called by mutect2, varscan2
- COL13A1 | c.1390G>A p.G464R (on ENST00000398978 / NM_001130103.2; = p.G407R on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62573475; called by muse, mutect2, varscan2
- COL14A1 | c.2471G>A p.G824E | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52864388; called by muse, varscan2
- COL14A1 | c.2743G>A p.V915M | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV52864398, COSV99920451; called by muse, mutect2, varscan2
- COL14A1 | c.2791G>A p.E931K | Missense Mutation (SNP) | VAF 90/144 reads (63%) | SIFT tolerated (0.83); PolyPhen benign (0.006); catalogued as COSV52859528; called by muse, varscan2
- COL14A1 | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.824); catalogued as COSV52864416; called by muse, varscan2
- COL14A1 | c.3731C>T p.S1244L | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV52864425; called by mutect2, varscan2
- COL17A1 | c.2684C>T p.S895L | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as rs760109253, COSV62225412; called by muse, mutect2, varscan2
- COL18A1 | c.4487G>A p.R1496Q (on ENST00000359759 / NM_130444.3; = p.R1261Q on NM_030582.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs199583095; called by mutect2, varscan2
- COL1A1 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 58/64 reads (91%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.495); catalogued as COSV56808450; called by muse, varscan2
- COL1A2 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 117/218 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV51963788; called by muse, mutect2, varscan2
- COL1A2 | c.2422G>A p.G808S | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51963799; called by muse, varscan2
- COL20A1 | c.2881G>A p.E961K | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV58924717; called by muse, mutect2, varscan2
- COL21A1 | c.2522C>T p.P841L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.946); catalogued as rs1486238937, COSV55166961; called by muse, mutect2, varscan2
- COL21A1 | c.2435G>A p.G812E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55170326; called by muse, mutect2, varscan2
- COL21A1 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55160911; called by muse, mutect2, varscan2
- COL22A1 | c.3917G>A p.G1306E | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57353348; called by muse, varscan2
- COL22A1 | c.3127G>A p.G1043S | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV57353358; called by muse, mutect2, varscan2
- COL24A1 | c.3349A>T p.K1117* | Nonsense Mutation (SNP) | VAF 66/172 reads (38%) | catalogued as COSV65311411; called by muse, mutect2, varscan2
- COL24A1 | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755961038, COSV65310873, COSV65313130; called by muse, varscan2
- COL2A1 | c.1894C>T p.P632S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV61533042; called by muse, varscan2
- COL3A1 | c.2245C>T p.P749S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs762257443, COSV58594507; called by muse, mutect2, varscan2
- COL3A1 | c.2867G>A p.R956Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV58581403; called by muse, mutect2, varscan2
- COL4A3 | c.1792C>T p.P598S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.621); catalogued as COSV67418657; called by muse, mutect2, varscan2
- COL4A3 | c.2745G>A p.R915= | Splice Region (SNP) | VAF 26/82 reads (32%) | catalogued as CD1312550, COSV67418665; called by muse, mutect2, varscan2
- COL4A4 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.88); PolyPhen benign (0.05); catalogued as COSV100306686; called by muse, mutect2, varscan2
- COL4A4 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.867); catalogued as COSV61632611; called by muse, mutect2, varscan2
- COL4A4 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61635142; called by muse, mutect2, varscan2
- COL5A1 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT tolerated (0.72); PolyPhen benign (0.039); catalogued as COSV65673287; called by muse, mutect2, varscan2
- COL5A2 | c.3481G>A p.G1161S | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100880605, COSV66413353; called by muse, mutect2, varscan2
- COL5A2 | c.3461C>T p.P1154L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66413364; called by muse, varscan2
- COL5A3 | c.4019G>A p.G1340E | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99318693; called by muse, mutect2
- COL5A3 | c.1169T>A p.F390Y | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.76); catalogued as COSV53416975; called by muse, mutect2, varscan2
- COL6A3 | c.5206G>A p.G1736S | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55103144; called by muse, mutect2, varscan2
- COL6A5 | c.7357G>A p.E2453K (on ENST00000312481; = p.E2449K on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55198362, COSV55202876; called by muse, mutect2, varscan2
- COL6A6 | c.1935G>A p.M645I | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.191); catalogued as COSV62019898; called by mutect2, varscan2
- COL7A1 | c.6685C>T p.P2229S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as CM014333, COSV60401037; called by muse, mutect2, varscan2
- COL7A1 | c.5738G>A p.G1913D | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM071651, COSV60401046; called by muse, mutect2, varscan2
- COL7A1 | c.4744C>T p.P1582S | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); catalogued as rs146418495; called by muse, mutect2, varscan2
- COL7A1 | c.3548C>T p.S1183F | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV60401062; called by muse, varscan2
- COL8A1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.353); catalogued as COSV53740053; called by muse, mutect2, varscan2
- COL9A1 | c.1604G>A p.G535E | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57890704; called by muse, mutect2, varscan2
- COL9A1 | c.1213C>T p.H405Y | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.134); catalogued as COSV57890738; called by mutect2, varscan2
- COL9A3 | c.1315G>A p.G439R | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59652064; called by muse, mutect2, varscan2
- CPA5 | c.899A>G p.E300G | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62570469; called by mutect2, varscan2
- CPE | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV68580683; called by mutect2, varscan2
- CPED1 | c.450G>A p.W150* | Nonsense Mutation (SNP) | VAF 120/230 reads (52%) | catalogued as rs1229319681, COSV100120537, COSV60005139; called by muse, mutect2, varscan2
- CPED1 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 120/228 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV60002662, COSV60017710; called by muse, mutect2, varscan2
- CPED1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1260513183, COSV60009973; called by mutect2, varscan2
- CPED1 | c.947G>A p.R316K | Missense Mutation (SNP) | VAF 83/142 reads (58%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as COSV60009988; called by muse, varscan2
- CPNE1 | c.1036C>T p.P346S (on ENST00000352393; = p.P351S on NM_003915.5) | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs1219453962, COSV58294033; called by muse, mutect2, varscan2
- CPXM2 | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99581940, COSV99583306; called by muse, mutect2, varscan2
- CR1L | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54324386, COSV99687997; called by muse, mutect2, varscan2
- CRB1 | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV66332555; called by muse, mutect2, varscan2
- CRB1 | c.2443G>A p.G815R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66332557; called by muse, mutect2, varscan2
- CREB3L3 | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.334); catalogued as COSV50250209; called by muse, mutect2, varscan2
- CREB5 | c.791C>T p.S264F (on ENST00000357727 / NM_182898.4; = p.S257F on NM_004904.3) | Missense Mutation (SNP) | VAF 124/300 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as rs377293245; called by muse, mutect2, varscan2
- CRH | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52542134; called by mutect2, varscan2
- CRH | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV99396193; called by mutect2, varscan2
- CRIM1 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV54870434; called by muse, varscan2
- CRMP1 | c.1369G>A p.G457R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1287440264, COSV61481644; called by muse, mutect2, varscan2
- CRYBG1 | c.3244G>A p.D1082N | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV64812898; called by muse, mutect2, varscan2
- CSF1 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV100294445; called by muse, mutect2, varscan2
- CSMD1 | c.3484G>A p.D1162N (on ENST00000520002; = p.D1161N on NM_033225.6) | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59365293; called by mutect2, varscan2
- CSMD1 | c.1981C>T p.P661S (on ENST00000520002; = p.P660S on NM_033225.6) | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1050099966, COSV59365325; called by muse, mutect2, varscan2
- CSMD2 | c.4682C>T p.P1561L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53894923; called by muse, varscan2
- CSMD2 | c.2459G>A p.G820E | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53946791, COSV99589705; called by muse, varscan2
- CSMD2 | c.1690A>T p.N564Y | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV53946819; called by mutect2, varscan2
- CSMD2 | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53946851; called by muse, mutect2, varscan2
- CSMD3 | c.9488G>A p.G3163E (on ENST00000297405 / NM_001363185.1; = p.G2994E on NM_052900.3) | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV52277605; called by muse, mutect2, varscan2
- CSMD3 | c.7213G>A p.E2405K (on ENST00000297405 / NM_001363185.1; = p.E2301K on NM_052900.3) | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); catalogued as COSV52116824; called by mutect2, varscan2
- CSMD3 | c.5698G>A p.V1900I (on ENST00000297405 / NM_001363185.1; = p.V1796I on NM_052900.3) | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.983); catalogued as COSV52096148, COSV52277654; called by muse, mutect2, varscan2
- CSMD3 | c.3073G>A p.D1025N (on ENST00000297405 / NM_001363185.1; = p.D921N on NM_052900.3) | Missense Mutation (SNP) | VAF 102/176 reads (58%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.752); catalogued as COSV52277681, COSV52307119; called by muse, mutect2, varscan2
- CSMD3 | c.130T>A p.F44I | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV52277709; called by muse, mutect2, varscan2
- CSN1S1 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as COSV55891728; called by muse, mutect2, varscan2
- CSN2 | c.587T>A p.L196H | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV61992506; called by mutect2, varscan2
- CSN2 | c.507G>A p.W169* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as rs1177842311, COSV61992515; called by muse, mutect2, varscan2
- CSRNP2 | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99950352; called by muse, mutect2, varscan2
- CSRNP3 | c.408G>A p.K136= | Splice Region (SNP) | VAF 8/27 reads (30%) | catalogued as COSV58783898; called by muse, mutect2, varscan2
- CSRNP3 | c.819G>A p.M273I | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV58780871; called by mutect2, varscan2
- CSTF2 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 34/38 reads (89%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV63376462; called by muse, mutect2, varscan2
- CTDP1 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs758282005, COSV50007763; called by muse, mutect2, varscan2
- CTIF | c.1598G>A p.R533Q | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as rs372476573; called by mutect2, varscan2
- CTNNA2 | c.2816C>T p.S939L (on ENST00000402739 / NM_001282597.3; = p.S891L on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as rs1052098013, COSV58132864; called by mutect2, varscan2
- CUBN | c.3343G>A p.E1115K | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV64709702; called by mutect2, varscan2
- CUBN | c.1979T>A p.L660H | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV104428206, COSV64723867; called by muse, mutect2, varscan2
- CUL4A | c.1384C>T p.L462F (on ENST00000375440 / NM_001008895.4; = p.L362F on NM_003589.3) | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58375057; called by muse, mutect2, varscan2
- CUL4B | c.2494-1G>A p.X832_splice | Splice Site (SNP) | VAF 60/68 reads (88%) | catalogued as COSV60690157; called by muse, mutect2, varscan2
- CUL5 | c.220A>G p.K74E | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.038); catalogued as COSV67609851; called by muse, mutect2, varscan2
- CUX2 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs771675208, COSV55638590; called by mutect2, varscan2
- CWC15 | c.670A>T p.M224L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.111); catalogued as rs1389158286, COSV54412281; called by muse, mutect2, varscan2
- CX3CR1 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64193990; called by muse, mutect2, varscan2
- CXCR3 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0.05); PolyPhen benign (0.298); catalogued as rs913064075, COSV65462239; called by mutect2, varscan2
- CXorf66 | c.457G>A p.G153R | Missense Mutation (SNP) | VAF 115/159 reads (72%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1389286261, COSV65169591, COSV65169646; called by muse, mutect2, varscan2
- CYB561A3 | c.539T>C p.F180S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV53653503; called by muse, varscan2
- CYBRD1 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV58427555; called by muse, mutect2, varscan2
- CYC1 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as rs1290121873, COSV59644867, COSV59644885; called by muse, mutect2, varscan2
- CYLC1 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs769298767, COSV61414922; called by muse, mutect2, varscan2
- CYP1A2 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV59660573; called by muse, mutect2, varscan2
- CYP1A2 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs766962627, COSV59660382, COSV59660583; called by muse, varscan2
- CYP2C8 | c.1291G>A p.G431R | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV64877961; called by muse, mutect2, varscan2
- CYP2C8 | c.642G>A p.Q214= | Splice Region (SNP) | VAF 13/45 reads (29%) | catalogued as COSV64878452; called by muse, mutect2, varscan2
- CYP2C9 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as rs745417361, COSV53248397, COSV99582442; called by muse, mutect2, varscan2
- CYP3A43 | c.990A>T p.K330N | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV55937471; called by muse, mutect2, varscan2
- CYP3A5 | c.72-1G>A p.X24_splice | Splice Site (SNP) | VAF 35/61 reads (57%) | catalogued as COSV99769704; called by muse, mutect2, varscan2
- CYP3A5 | c.72-2A>G p.X24_splice | Splice Site (SNP) | VAF 34/60 reads (57%) | catalogued as COSV56122097; called by muse, mutect2, varscan2
- CYP3A7 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 130/160 reads (81%) | SIFT deleterious (0.04); PolyPhen benign (0.226); catalogued as COSV60482865; called by muse, mutect2, varscan2
- CYP46A1 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 55/66 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as COSV55896126; called by muse, mutect2, varscan2
- CYP4X1 | c.1356-1G>A p.X452_splice | Splice Site (SNP) | VAF 68/185 reads (37%) | catalogued as COSV64151531; called by muse, mutect2, varscan2
- CYRIA | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.654); catalogued as COSV62864368, COSV62866545; called by muse, mutect2, varscan2
- CYRIA | c.479G>A p.R160K | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs267598965, COSV62866550; called by muse, mutect2, varscan2
- DAB1 | c.656T>A p.I219N | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV59734583; called by muse, varscan2
- DAB1 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59730408; called by muse, mutect2, varscan2
- DAB2 | c.2291C>T p.P764L | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs759746894, COSV57917769; called by muse, varscan2
- DAB2 | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1282305948, COSV57916793; called by muse, mutect2, varscan2
- DAO | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57323988; called by muse, mutect2, varscan2
- DAW1 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as COSV59367923; called by mutect2, varscan2
- DBX2 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.084); catalogued as COSV60339138; called by mutect2, varscan2
- DCAF12 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 49/56 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1425585123, COSV63513406; called by muse, mutect2, varscan2
- DCAF16 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV66384343; called by muse, mutect2, varscan2
- DCAF17 | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV59830992; called by muse, mutect2, varscan2
- DCC | c.4186C>T p.P1396S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV71431528; called by muse, mutect2, varscan2
- DCDC1 | c.5152C>T p.Q1718* (on ENST00000597505 / NM_001367979.1; = p.Q825* on NM_020869.3) | Nonsense Mutation (SNP) | VAF 26/56 reads (46%) | catalogued as rs769838213, COSV58002065; called by mutect2, varscan2
- DCDC1 | c.3994G>A p.E1332K (on ENST00000597505 / NM_001367979.1; = p.E439K on NM_020869.3) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV58002077; called by muse, mutect2, varscan2
- DCDC1 | c.2959G>A p.E987K (on ENST00000597505 / NM_001367979.1; = p.E94K on NM_020869.3) | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV60310537; called by muse, mutect2, varscan2
- DCN | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50008499; called by muse, mutect2, varscan2
- DCN | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 44/124 reads (35%) | catalogued as COSV50008510; called by muse, varscan2
- DCN | c.322C>T p.H108Y | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV50008521; called by mutect2, varscan2
- DCST2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55053826; called by muse, varscan2
- DCX | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 44/53 reads (83%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as rs753011298, COSV57573868; called by mutect2, varscan2
- DDR1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61323956; called by muse, mutect2, varscan2
- DDX3X | c.928C>T p.R310* (on ENST00000399959; = p.R311* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 120/139 reads (86%) | catalogued as CM158047, COSV67863633; called by muse, mutect2, varscan2
- DEFA5 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs772513382, COSV57962438; called by muse, mutect2, varscan2
- DEFB115 | c.131G>A p.R44K | Missense Mutation (SNP) | VAF 57/87 reads (66%) | SIFT tolerated (0.98); PolyPhen benign (0.013); catalogued as rs1337721339, COSV68723383; called by muse, mutect2, varscan2
- DENND2A | c.2685G>C p.L895F | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52056747; called by muse, mutect2, varscan2
- DEPDC1 | c.1987C>T p.L663F (on ENST00000456315 / NM_001114120.3; = p.L379F on NM_017779.6) | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63958797; called by muse, mutect2, varscan2
- DEPDC5 | c.2891C>T p.S964F (on ENST00000400246; = p.S1033F on NM_014662.5) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV56706440, COSV56707493; called by muse, mutect2, varscan2
- DES | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1429678305, COSV64660659; called by muse, mutect2, varscan2
- DGKB | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51802656, COSV51809367; called by muse, mutect2, varscan2
- DGKI | c.3118G>A p.D1040N | Missense Mutation (SNP) | VAF 82/94 reads (87%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV55950781; called by muse, mutect2, varscan2
- DGKZ | c.779C>T p.T260I (on ENST00000454345 / NM_001105540.2; = p.T71I on NM_003646.4) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as COSV58993348; called by muse, mutect2, varscan2
- DHTKD1 | c.2661C>T p.L887= | Splice Region (SNP) | VAF 112/328 reads (34%) | catalogued as COSV53805894; called by muse, mutect2, varscan2
- DHX57 | c.2176C>T p.P726S | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54889628; called by muse, mutect2, varscan2
- DIAPH3 | c.1650+1G>A p.X550_splice (on ENST00000400324 / NM_001042517.2; = p.X287_splice on NM_030932.3) | Splice Site (SNP) | VAF 28/85 reads (33%) | catalogued as COSV57377879, COSV57380265; called by muse, mutect2, varscan2
- DIRAS1 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60215858; called by mutect2, varscan2
- DKK2 | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as COSV53401720; called by muse, mutect2, varscan2
- DLAT | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as rs1555181180, COSV99734638; called by muse, mutect2, varscan2
- DLG2 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV54674113; called by muse, mutect2, varscan2
- DLGAP1 | c.2308G>A p.D770N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59826197; called by muse, mutect2, varscan2
- DLX3 | c.299A>G p.E100G | Missense Mutation (SNP) | VAF 51/57 reads (89%) | SIFT tolerated (0.15); PolyPhen benign (0.121); catalogued as rs1477606750, COSV101460545; called by muse, mutect2, varscan2
- DLX3 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 50/56 reads (89%) | catalogued as COSV101460546; called by mutect2, varscan2
- DMBT1 | c.7160C>T p.S2387F (on ENST00000338354 / NM_001377530.1; = p.S1630F on NM_004406.3) | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV57535809, COSV57541035; called by muse, mutect2, varscan2
- DMBX1 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as COSV63602087; called by muse, varscan2
- DMBX1 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV63601642, COSV63602450; called by muse, mutect2, varscan2
- DMPK | c.1211C>T p.S404F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1320270393, COSV52181211; called by muse, mutect2, varscan2
- DMXL2 | c.2848C>T p.P950S | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV51853194; called by muse, mutect2, varscan2
- DNAH10 | c.1538G>A p.R513Q (on ENST00000409039; = p.R452Q on NM_207437.3) | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs1355478360, COSV68999131; called by muse, mutect2, varscan2
- DNAH10 | c.4018G>A p.E1340K (on ENST00000409039; = p.E1279K on NM_207437.3) | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as COSV68999141; called by muse, mutect2, varscan2
- DNAH17 | c.4540C>T p.P1514S | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV67759417; called by muse, mutect2, varscan2
- DNAH17 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0.132); catalogued as rs765950730, COSV67759421; called by muse, mutect2, varscan2
- DNAH2 | c.6305C>T p.S2102F | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT tolerated (0.09); PolyPhen benign (0.392); catalogued as COSV66724221; called by muse, mutect2, varscan2
- DNAH3 | c.12112C>T p.L4038F | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.023); catalogued as COSV54542360, COSV54542737; called by muse, mutect2, varscan2
- DNAH3 | c.8424G>A p.M2808I | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1364545089, COSV54542761; called by mutect2, varscan2
- DNAH5 | c.12631G>A p.E4211K | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762673561, COSV54204698, COSV54216995; ClinVar: uncertain significance; called by mutect2, varscan2
- DNAH5 | c.11533C>T p.R3845C | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as rs565819640, COSV54230332; ClinVar: uncertain significance; called by mutect2, varscan2
- DNAH5 | c.10772G>A p.G3591E | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54214966, COSV99451847; called by muse, mutect2, varscan2
- DNAH5 | c.10576G>A p.A3526T | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs868745747, COSV54253123, COSV99448765; called by muse, mutect2, varscan2
- DNAH5 | c.8650G>A p.E2884K | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs866483972, COSV54231911; called by muse, varscan2
- DNAH5 | c.7225C>T p.L2409F | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV54206564; called by muse, mutect2, varscan2
- DNAH5 | c.5508G>A p.M1836I | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV54222664, COSV54244587; called by muse, mutect2, varscan2
- DNAH5 | c.2839G>A p.E947K | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV54216359, COSV54220736; called by muse, mutect2, varscan2
- DNAH6 | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as rs111548143, COSV52877008; called by mutect2, varscan2
- DNAH7 | c.10367C>T p.S3456L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.143); catalogued as COSV100414906; called by mutect2, varscan2
- DNAH7 | c.9905G>A p.W3302* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as rs753921470, COSV56779447; called by muse, mutect2, varscan2
- DNAH7 | c.5651G>A p.R1884Q | Missense Mutation (SNP) | VAF 63/75 reads (84%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs201751336; called by muse, mutect2, varscan2
- DNAH7 | c.2302C>T p.R768C | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs192646926; called by mutect2, varscan2
- DNAH8 | c.1807C>T p.P603S | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.511); catalogued as rs1322197957, COSV59422707; called by muse, mutect2, varscan2
- DNAH8 | c.1808C>T p.P603L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV100544641; called by muse, mutect2, varscan2
- DNAH8 | c.2007G>A p.M669I | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV59471216; called by mutect2, varscan2
- DNAH8 | c.6997C>T p.P2333S | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.299); catalogued as COSV59468361; called by muse, mutect2, varscan2
- DNAH8 | c.10061C>T p.S3354F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59471276; called by muse, mutect2, varscan2
- DNAH9 | c.1519-1G>A p.X507_splice | Splice Site (SNP) | VAF 38/52 reads (73%) | catalogued as COSV52348484, COSV52368981; called by muse, mutect2, varscan2
- DNAH9 | c.7238C>T p.S2413F | Missense Mutation (SNP) | VAF 44/50 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV52347417, COSV52368989; called by muse, mutect2, varscan2
- DNAI2 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 70/82 reads (85%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.683); catalogued as COSV56757360; called by mutect2, varscan2
- DNAJC21 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.355); catalogued as rs1561183481, COSV57762022; called by muse, mutect2, varscan2
- DNAJC5B | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 64/96 reads (67%) | SIFT tolerated (0.51); PolyPhen benign (0.041); catalogued as rs141686243, COSV52535470; called by mutect2, varscan2
- DNASE1L3 | c.802-1G>A p.X268_splice | Splice Site (SNP) | VAF 20/59 reads (34%) | catalogued as COSV100568685; called by muse, mutect2, varscan2
- DNMBP | c.4085C>T p.S1362F | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60630942; called by muse, varscan2
- DNMBP | c.4033C>T p.P1345S | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.538); catalogued as COSV60630962; called by muse, varscan2
- DNMBP | c.3274T>C p.F1092L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60630980; called by muse, mutect2, varscan2
- DNMT1 | c.4246-1G>A p.X1416_splice | Splice Site (SNP) | VAF 4/20 reads (20%) | catalogued as COSV61582385; called by muse, mutect2
- DOCK10 | c.3973C>T p.R1325* | Nonsense Mutation (SNP) | VAF 56/156 reads (36%) | catalogued as COSV51349418; called by mutect2, varscan2
- DOCK2 | c.5056C>T p.P1686S | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT tolerated (0.87); PolyPhen benign (0.01); catalogued as rs1391893436, COSV56979405; called by muse, mutect2, varscan2
- DOCK4 | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1315373989, COSV70324925; called by muse, mutect2, varscan2
- DOCK8 | c.5173G>A p.E1725K | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs747368033, COSV66619811; called by mutect2, varscan2
- DOK3 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 11/11 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV57253927; called by muse, mutect2, varscan2
- DOK5 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 87/149 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs1426025722, COSV52824017; called by muse, mutect2, varscan2
- DOP1A | c.6698C>T p.P2233L | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV52715538; called by muse, mutect2, varscan2
- DPP10 | c.765G>A p.M255I | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs780261919, COSV59711997; called by mutect2, varscan2
- DPPA3 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV100559921, COSV61503207; called by muse, mutect2, varscan2
- DPPA5 | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV64875899; called by mutect2, varscan2
- DPY19L4 | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 138/263 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1475847935, COSV68962166; called by muse, mutect2, varscan2
- DPYD | c.2276G>A p.R759Q | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as rs267598786, COSV64609998; ClinVar: uncertain significance; called by mutect2, varscan2
- DPYD | c.1257G>A p.W419* | Nonsense Mutation (SNP) | VAF 49/102 reads (48%) | catalogued as COSV64610004; called by muse, mutect2, varscan2
- DPYD | c.767T>A p.I256N | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV64610009; called by muse, mutect2
- DPYS | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as rs751818026, COSV60907008; called by muse, mutect2, varscan2
- DPYS | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as COSV59827218; called by muse, varscan2
- DPYS | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs765884757, COSV60906455; ClinVar: uncertain significance; called by mutect2, varscan2
- DRD1 | c.1025C>T p.S342L | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV67105085; called by mutect2, varscan2
- DRD2 | c.480G>A p.W160* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100669536; called by muse, mutect2, varscan2
- DRD5 | c.1063A>G p.N355D | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58579752; called by muse, mutect2, varscan2
- DSC1 | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.478); catalogued as COSV57149775; called by mutect2, varscan2
- DSC2 | c.2318G>A p.G773E | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV51867943; called by muse, mutect2, varscan2
- DSCAM | c.4390G>A p.E1464K | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1371989999, COSV68021628; called by muse, mutect2, varscan2
- DSCAM | c.2755G>A p.D919N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101261371, COSV68033183; called by mutect2, varscan2
- DSCAM | c.2225G>A p.R742Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV68027081, COSV68029910; called by muse, mutect2, varscan2
- DSCAM | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.995); catalogued as COSV68033194; called by muse, varscan2
- DSCAML1 | c.3136C>T p.P1046S (on ENST00000321322; = p.P986S on NM_020693.4) | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV58399549; called by muse, mutect2, varscan2
- DSG1 | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99935897; called by muse, varscan2
- DSG1 | c.2132G>A p.G711E | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV57138414; called by muse, mutect2, varscan2
- DSG3 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as COSV57128639; called by muse, mutect2, varscan2
- DSG3 | c.1991G>A p.G664E | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as rs1361767559, COSV57124023; called by muse, mutect2, varscan2
- DSG3 | c.2358G>A p.M786I | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); catalogued as rs767532668, COSV57128646; called by muse, varscan2
- DSP | c.3057G>T p.E1019D | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.967); catalogued as COSV65794718; called by mutect2, varscan2
- DTL | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65342979; called by muse, mutect2, varscan2
- DTNA | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs376007740; called by muse, mutect2, varscan2
- DTX3L | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV99949970; called by muse, mutect2, varscan2
- DTX3L | c.2078G>T p.R693L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV56144542, COSV56145221; called by muse, mutect2, varscan2
- DTX4 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV57093851; called by muse, mutect2, varscan2
- DUSP8 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59031121; called by muse, mutect2, varscan2
- DYNAP | c.499C>T p.P167S (on ENST00000321600; = p.P141S on NM_173629.3) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1193539530, COSV100391704, COSV58666828; called by muse, mutect2, varscan2
- DYNC1I1 | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 63/190 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.298); catalogued as COSV61468363; called by muse, mutect2, varscan2
- DYSF | c.3597G>A p.W1199* | Nonsense Mutation (SNP) | VAF 23/58 reads (40%) | catalogued as COSV50524491, COSV99249728; called by muse, mutect2, varscan2
- ECPAS | c.1137C>T p.T379= | Splice Region (SNP) | VAF 15/18 reads (83%) | catalogued as COSV52198044, COSV52204827; called by muse, mutect2, varscan2
- EDA2R | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV53632521; called by muse, mutect2, varscan2
- EDNRA | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV60099679; called by muse, varscan2
- EEFSEC | c.937C>T p.H313Y | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV54630833; called by muse, varscan2
- EFCAB13 | c.1516G>A p.G506R | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs967559742, COSV58951482; called by muse, mutect2, varscan2
- EFCAB6 | c.2750C>T p.S917L | Missense Mutation (SNP) | VAF 100/237 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs762875526, COSV53067265; called by mutect2, varscan2
- EFCAB6 | c.2206C>T p.P736S | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.889); catalogued as COSV53068717; called by muse, mutect2, varscan2
- EFEMP1 | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | catalogued as rs1457592887, COSV100816971, COSV62617427; called by muse, mutect2, varscan2
- EGF | c.760C>T p.L254F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99490790; called by muse, mutect2, varscan2
- EGFLAM | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59313148, COSV59319575; called by muse, varscan2
- EGFLAM | c.1055G>A p.C352Y | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59313183; called by mutect2, varscan2
- EIF3I | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 172/388 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as rs1442633190, COSV61890216; called by muse, mutect2, varscan2
- EIF4A2 | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV56216995; called by muse, mutect2, varscan2
- EIF4G2 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60596814; called by mutect2, varscan2
- ELF1 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.996); catalogued as COSV53501660; called by muse, mutect2, varscan2
- ELMOD1 | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56195057; called by muse, mutect2, varscan2
- ELOA2 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.161); catalogued as rs769385321, COSV55294609; called by muse, mutect2, varscan2
- ELP3 | c.1381T>A p.F461I | Missense Mutation (SNP) | VAF 34/43 reads (79%) | SIFT tolerated (0.08); PolyPhen benign (0.213); catalogued as COSV56460903; called by mutect2, varscan2
- EMB | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57483797; called by muse, mutect2, varscan2
- EML5 | c.1528G>A p.G510R | Missense Mutation (SNP) | VAF 47/62 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61350465; called by muse, mutect2, varscan2
- EML5 | c.1265A>T p.Y422F | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV61350473; called by muse, mutect2, varscan2
- ENAM | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV68536739; called by muse, mutect2, varscan2
- ENPEP | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as COSV54448195, COSV54455737; called by muse, varscan2
3,429 further variants in this file (1,919 protein-altering or splice-affecting, 1,420 silent, 90 other) are not listed here.
